Gene-level copy-number profile of tumor specimen TCGA-FJ-A3ZF-01A from TCGA case TCGA-FJ-A3ZF, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 73.4 years (26,825 days).
Specimen TCGA-FJ-A3ZF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.0917f4e4-4944-4547-ab1d-e90eb1cb5526.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FJ-A3ZF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/84a0b624-7abd-4b8b-95df-2929206296e7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 841; copy number 2: 12,470; copy number 3: 20,735; copy number 4: 13,238; copy number 5: 7,857; copy number 6: 3,377; copy number 7: 882; copy number 8: 236; copy number 9: 117; copy number 11: 4; copy number 27: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FJ-A3ZF-01A-11D-A23L-01): tumor purity 0.88, ploidy 3.1, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,291 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,913,184–121,580,524, 22 genes, copy number 7: LINC00623, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr1:188,705,623–188,732,208, 1 gene, copy number 11: AL691515.1.
- chr1:191,146,025–194,931,310, 40 genes, copy number 9: HNRNPA1P46, AL713866.1, AL713866.2, LINC01680, LINC02770, AL359081.1, RGS18, AL390957.1, AL513175.1, AL513175.2, RGS21, AL136987.1, RGS1, RGS13, RPS27AP5, MIR4426, AL035407.2, AL035407.1, RGS2, RN7SKP126, ZNF101P2, UCHL5, SCARNA18B, RO60, GLRX2, CDC73, MIR1278, B3GALT2, Metazoa_SRP, LINC01031, AL138778.1, AL136456.1, AL357793.1, AL357793.2, RPL23AP22, EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1, AL353072.2.
- chr1:196,044,883–199,393,307, 44 genes, copy number 9 (within-gene range 4–9): LINC01724, KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9, NEK7, PRR13P1, AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789.
- chr2:9,488,486–9,556,732, 1 gene, copy number 7 (within-gene range 6–7): ADAM17.
- chr2:9,555,899–11,178,870, 48 genes, copy number 7 (within-gene range 4–7): AC073195.1, YWHAQ, Y_RNA, AC082651.1, AC082651.4, RNU4-73P, AC082651.2, AC082651.3, TAF1B, AC010969.2, AC010969.3, GRHL1, AC010969.1, AC104794.4, AC104794.3, KLF11, AC104794.5, CYS1, AC104794.2, AC104794.1, RRM2, AC007240.1, MIR4261, RN7SL66P, AC007240.3, AC007240.2, HPCAL1, ODC1, SNORA80B, ODC1-DT, NOL10, AC007314.1, RN7SL832P, Metazoa_SRP, AC092687.2, ATP6V1C2, RNU7-138P, AC092687.3, PDIA6, RNU7-176P, LINC01954, AC092687.1, AC079587.1, KCNF1, RPL6P4, AC062028.1, C2orf50, SLC66A3.
- chr2:158,658,337–158,753,775, 3 genes, copy number 7: PKP4-AS1, AC005042.1, AC005042.2.
- chr2:179,399,728–183,215,414, 47 genes, copy number 7–9: RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22, AC012669.1, AC009478.1, SCHLAP1, AC104820.1, FTH1P20, RPL27AP3, UBE2E3, AC104076.1, AC068196.1, LINC01934, MIR4437, AC020595.1, ITGA4, CERKL, NEUROD1, AC013733.2, AC013733.1, SAP18P2, RNU6ATAC19P, AC009962.1, ITPRID2, PPP1R1C, KRT18P29, RNA5SP113, PDE1A, AC012500.1, RN7SL267P, DNAJC10, RPL31P15, Y_RNA, FRZB, RNU6-1122P, NCKAP1, Y_RNA, AC064871.1, KRT8P10, DUSP19, AC064871.2, NUP35, AC021851.1.
- chr2:189,031,898–191,020,960, 37 genes, copy number 7 (within-gene range 4–7): COL5A2, AC133106.1, MIR3129, KRT18P19, WDR75, KDM3AP1, AC013439.1, SLC40A1, AC012488.1, ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1, C2orf88, TERF1P6, HNRNPCP2, RNF11P1, MSTN, HIBCH, INPP1, MFSD6, AC093388.1, NEMP2, AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1.
- chr2:192,629,919–193,277,614, 8 genes, copy number 7–11: AC062039.1, AC013401.1, PCGEM1, RPS17P8, AC013401.2, AC096647.1, SLC44A3P1, DNAJC17P1.
- chr6:20,401,879–24,751,960, 52 genes, copy number 27: E2F3, RN7SL128P, E2F3-IT1, RNU6-141P, Y_RNA, CDKAL1, AL035090.1, AL513188.1, RNU6-150P, AL451080.1, AL031767.1, AL031767.2, LINC00581, AL512380.1, AL512380.2, SOX4, BOLA2P3, CASC15, AL136313.1, RN7SKP240, NBAT1, AL359694.1, PRL, HDGFL1, AL033539.1, AL033539.2, AL035401.1, AL591416.1, RNU6-1060P, AL139231.1, AL133270.1, AL139093.1, SPTLC1P2, AL032822.1, HNRNPA1P58, NRSN1, FO393410.1, DCDC2, KAAG1, RNU6-391P, MRS2, GPLD1, ALDH5A1, KIAA0319, KRT8P43, TDP2, ACOT13, AL031775.1, C6orf62, AL031775.2, LINC02828, AL133264.1.
- chr6:122,643,388–122,809,720, 5 genes, copy number 9: AL512283.1, AL512283.3, RN7SL564P, FABP7, SMPDL3A.
- chr6:167,237,508–168,820,656, 32 genes, copy number 7 (within-gene range 5–7): AL353747.3, AL353747.2, UNC93A, TTLL2, AL021331.1, TCP10L3, AL356123.1, LINC02538, AL356123.2, LINC02487, AL009178.1, LINC01558, AL009178.2, AL009178.3, AFDN-DT, AFDN, HGC6.3, KIF25-AS1, KIF25, FRMD1, AL611929.1, AL606970.5, AL606970.4, AL606970.2, AL606970.3, CTAGE13P, DACT2, AL606970.1, AL138918.1, SMOC2, AL136099.1, AL513210.2.
- chr7:70,972–28,279,700, 493 genes, copy number 7–8 (broad region; genes not listed).
- chr7:63,011,463–72,447,151, 229 genes, copy number 7–8 (broad region; genes not listed).
- chr8:116,642,130–117,318,701, 13 genes, copy number 7: EIF3H, UTP23, RAD21, RAD21-AS1, MIR3610, AARD, SLC30A8, RN7SL228P, AC027419.1, AC027419.2, RN7SL826P, AC084114.1, AP002848.1.
- chr18:47,390–9,538,114, 189 genes, copy number 8 (broad region; genes not listed).
- chr18:26,655,737–29,361,963, 27 genes, copy number 8: AQP4-AS1, AC012588.1, PCAT18, U3, AC018371.1, AC018371.2, AQP4, CHST9, ATP6V1E1P2, LINC01908, AC090403.1, AC021382.1, UBA52P9, AC068408.1, RBM22P1, PA2G4P3, AC068408.2, AC090936.1, CDH2, AC110015.1, AC006249.1, AC090365.1, ARIH2P1, AC023932.1, RNU6-408P, AC105245.1, AC074237.1.

Autosomal genes at a single copy (total copy number 1): 841. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
